Somatic mutation profile of tumor specimen TCGA-IG-A51D-01A (aliquot TCGA-IG-A51D-01A-11D-A27G-09) from TCGA case TCGA-IG-A51D, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.7 years (23,259 days).
Specimen TCGA-IG-A51D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef802554-20d7-473f-8771-6a1d8ba8ac4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A51D-10A (Blood Derived Normal), aliquot TCGA-IG-A51D-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4ea4ff31-4b53-4d87-b24d-acd6e340b92d

The open-access MAF lists 153 somatic variants for this specimen: 114 protein-altering or splice-affecting, 35 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 35, Nonsense Mutation 6, Splice Site 3, Frame Shift Del 3, In Frame Del 2, RNA 2, Frame Shift Ins 1, 5'UTR 1, Splice Region 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.3878+1G>A p.X1293_splice | Splice Site (SNP) | VAF 14/30 reads (47%) | hotspot (GDC flag); catalogued as COSV65042412; called by muse, mutect2, varscan2
- ABCG8 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV55393214; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs376039296, COSV101002103; called by muse, mutect2, varscan2
- ADSL | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs371892194; called by muse, mutect2, varscan2
- ATP13A2 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs139065780; called by muse, mutect2, varscan2
- BSN | c.6553G>C p.A2185P | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV56516623; called by muse, mutect2, varscan2
- CAMKK2 | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396496439, COSV61213338; called by muse, mutect2, varscan2
- CEP104 | c.891+1G>T p.X297_splice | Splice Site (SNP) | VAF 16/75 reads (21%) | catalogued as rs1432015766; called by muse, mutect2, varscan2
- CEP170B | c.3865G>A p.A1289T (on ENST00000453495; = p.A1218T on NM_015005.3) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.92); catalogued as rs1380250808; called by muse, mutect2, varscan2
- CFHR3 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs779855453, COSV66401561; called by muse, mutect2, varscan2
- CHD5 | c.2559G>T p.K853N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99313715; called by muse, mutect2, varscan2
- CNTNAP5 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101442996; called by muse, mutect2, varscan2
- CTSH | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as rs1196977462; called by muse, mutect2, varscan2
- CYP11B2 | c.840C>A p.F280L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59996686; called by muse, mutect2
- DAB2IP | c.3128C>T p.A1043V (on ENST00000408936; = p.A1015V on NM_032552.3) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs868409347; called by muse, mutect2
- DNAH5 | c.9287G>A p.R3096Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1388732051, COSV54203252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ETFDH | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as CM093456; called by muse, mutect2
- FABP4 | c.377C>T p.T126M | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as rs1470977675; called by muse, mutect2, varscan2
- FUCA2 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs757296473; called by muse, mutect2, varscan2
- GLB1L3 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.625); catalogued as rs766442756; called by muse, mutect2, varscan2
- GLP2R | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs114514574, COSV52322088; called by muse, mutect2, varscan2
- GSTA5 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as rs1448575093; called by muse, mutect2, varscan2
- HCN1 | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV57540581; called by muse, mutect2, varscan2
- IL23R | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs375054504; called by mutect2, varscan2
- IMPG2 | c.3524G>C p.G1175A | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV51972909; called by muse, mutect2, varscan2
- KCNQ3 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66471099; called by muse, mutect2, varscan2
- KIF18A | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as rs1279447558; called by muse, mutect2, varscan2
- MYH13 | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52834689; called by muse, mutect2, varscan2
- N4BP2L2 | c.2033C>T p.P678L (on ENST00000674422; = p.P249L on NM_033111.4) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.054); catalogued as COSV100679319; called by muse, mutect2, varscan2
- NAV3 | c.7G>C p.V3L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57086557; called by mutect2, varscan2
- NRBP1 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51995308; called by muse, mutect2, varscan2
- NXPH1 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as COSV68319806; called by muse, mutect2, varscan2
- OR2T6 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs865984223, COSV100861560, COSV63216427; called by muse, mutect2
- OR5W2 | c.808C>A p.Q270K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV100747611; called by muse, mutect2, varscan2
- PCDHA7 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV65344410; called by muse, mutect2, varscan2
- PCLO | c.10304G>A p.R3435Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.387); catalogued as rs775369053, COSV61620385; called by muse, mutect2, varscan2
- PDE1B | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV54494734; called by muse, mutect2, varscan2
- PGBD5 | c.895G>A p.A299T (on ENST00000525115; = p.A368T on NM_001258311.2) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs371374137; called by muse, mutect2, varscan2
- PLXND1 | c.3294G>C p.Q1098H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100140333; called by muse, mutect2
- POLR1F | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs527876640, COSV55999170; called by muse, mutect2, varscan2
- PPP3R2 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.351); catalogued as COSV62459146; called by muse, mutect2, varscan2
- PRX | c.2010G>T p.M670I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV52530434; called by muse, mutect2, varscan2
- RELN | c.9357G>C p.M3119I | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.854); catalogued as COSV59009100; called by muse, mutect2
- RYR2 | c.6450G>C p.M2150I | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as COSV63710988; called by muse, mutect2
- RYR2 | c.14553C>A p.F4851L | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1291829047, CM0911018, COSV63701021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHANK2 | c.3260G>A p.R1087H | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs910196065; called by muse, mutect2
- ST8SIA3 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 9/32 reads (28%) | PolyPhen possibly damaging (0.522); catalogued as COSV60653457; called by muse, mutect2, varscan2
- STAT2 | c.2060G>A p.R687Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs1196807040, COSV58477092; ClinVar: uncertain significance; called by muse, mutect2
- STX6 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV99275761; called by muse, mutect2
- TENT5D | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100382987; called by muse, mutect2, varscan2
- TMC6 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as rs760748540; called by muse, mutect2, varscan2
- TP53 | c.713_714del p.C238* | Frame Shift Del (DEL) | VAF 132/310 reads (43%) | catalogued as rs1555525539; called by pindel, varscan2
- UTP3 | c.864G>C p.R288S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV54661351; called by muse, mutect2, varscan2
- WDR6 | c.2573C>G p.P858R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58246393; called by muse, mutect2, varscan2
- XRRA1 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748191489; called by muse, mutect2, varscan2
- ALDH1L2 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANGPT1 | c.371C>A p.T124K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- B4GAT1 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BHMT | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- C10orf90 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CNTN6 | c.2534A>G p.D845G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- CPD | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP2A13 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJC13 | c.6022G>A p.E2008K | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.427); called by muse, mutect2
- DQX1 | c.2087C>A p.A696E | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- EDEM2 | c.703-1G>A p.X235_splice | Splice Site (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- EP300 | c.4190_4207del p.Y1397_H1402del | In Frame Del (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- FLG | c.9176C>A p.S3059* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | called by mutect2, varscan2
- FSTL4 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- GOLGA3 | c.3999G>C p.E1333D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- GUF1 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HELB | c.2329G>T p.G777C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCNAB1 | c.1246G>C p.D416H (on ENST00000490337 / NM_172160.3; = p.D405H on NM_003471.3) | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2
- KCNQ2 | c.1966G>C p.E656Q (on ENST00000359125 / NM_172107.4; = p.E628Q on NM_004518.6) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- KIR2DL1 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.206); called by muse, mutect2
- KRTAP9-3 | c.408G>C p.E136D | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- LIMK2 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- LRRC47 | c.1412dup p.V472Gfs*2 | Frame Shift Ins (INS) | VAF 15/85 reads (18%) | called by mutect2, pindel, varscan2
- MAGEL2 | c.2765G>T p.W922L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MAPKBP1 | c.4113G>T p.Q1371H (on ENST00000456763 / NM_001128608.2; = p.Q1365H on NM_014994.3) | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MARCKSL1 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- MATN2 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- MYBPC3 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ODF3L2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR1L1 | c.523G>T p.A175S (on ENST00000373686; = p.A125S on NM_001005236.3) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- OR2D3 | c.903G>C p.L301F | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- OR5T3 | c.514_526del p.I172Lfs*45 | Frame Shift Del (DEL) | VAF 17/129 reads (13%) | called by mutect2, pindel
- PITRM1 | c.124C>G p.L42V | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLOD2 | c.1003A>G p.K335E | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PREX1 | c.4468C>A p.Q1490K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- PZP | c.433T>C p.F145L | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); called by mutect2, varscan2
- RAB11FIP1 | c.1888T>A p.L630M | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- RARRES1 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RBBP7 | c.1110_1111del p.G371Tfs*4 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- RBM19 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- RDX | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- RHOBTB3 | c.1749C>A p.H583Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- RNF19B | c.1065T>G p.I355M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SATB2 | c.905T>A p.L302H | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SDK1 | c.5220C>G p.Y1740* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- SEPTIN11 | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- SIGIRR | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SKP2 | c.257_273delinsGAGAA p.K86_N91delinsRE | In Frame Del (DEL) | VAF 12/63 reads (19%) | called by pindel, varscan2*
- SLC22A6 | c.530C>A p.T177N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLC4A1AP | c.1764G>A p.K588= | Splice Region (SNP) | VAF 6/33 reads (18%) | called by mutect2, varscan2
- SNX1 | c.1219C>A p.R407S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SPECC1L | c.2678C>G p.S893* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- TAF5L | c.235A>G p.N79D | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- TRAV12-1 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPM8 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TTC31 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- TTN | c.96647A>G p.Q32216R (on ENST00000591111; = p.Q24792R on NM_003319.4) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- TUBA1C | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- WDR61 | c.588G>C p.L196F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- ACOX1 | c.84G>A p.E28= | Silent (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- AGMO | c.855C>T p.F285= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as rs772554565, COSV61108565, COSV61113252; called by muse, mutect2, varscan2
- BTN3A3 | c.1614G>A p.P538= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as rs757126334, COSV55074378; called by muse, mutect2, varscan2
- CNBD1 | c.894T>C p.Y298= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs774645211; called by muse, mutect2, varscan2
- CSF2RA | c.528G>T p.V176= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV62624012; called by muse, mutect2, varscan2
- CTNNAL1 | c.924G>A p.E308= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1199727544, COSV57701622, COSV57705162; called by muse, mutect2, varscan2
- CYP2A13 | c.741C>T p.F247= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV57836899, COSV57839561; called by muse, mutect2, varscan2
- DOCK8 | c.3150C>T p.I1050= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- EBLN2 | c.342A>G p.A114= | Silent (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- FNIP2 | c.1998C>A p.P666= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100033395; called by muse, mutect2, varscan2
- GPS1 | c.105C>T p.Y35= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs910929184; called by muse, mutect2, varscan2
- GRID1 | c.2286C>T p.G762= | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- HUNK | c.999C>G p.T333= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99528793; called by muse, mutect2, varscan2
- KLHL1 | c.849G>A p.E283= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100917342; called by muse, mutect2, varscan2
- LGALS9C | c.357C>T p.F119= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs749828933, COSV60195403; called by muse, mutect2
- LILRA2 | c.273C>T p.H91= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs757664099; called by muse, mutect2, varscan2
- MAB21L1 | c.399G>A p.Q133= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV100079812; called by muse, mutect2
- MTMR10 | c.345G>A p.K115= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100076124, COSV100076252; called by muse, mutect2, varscan2
- MUC16 | c.39867T>G p.S13289= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- NR2E3 | c.954G>A p.T318= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs779314442, COSV58908197; ClinVar: likely benign; called by muse, mutect2, varscan2
- PAPPA2 | c.858G>A p.A286= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as COSV100866629, COSV62785865, COSV62789208; called by muse, mutect2, varscan2
- PCDH17 | c.1941G>A p.T647= | Silent (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- PCDHA9 | c.171G>A p.A57= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV65332031, COSV65334297; called by muse, mutect2, varscan2
- PHF20 | c.2826G>A p.L942= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- PPL | c.2406G>A p.E802= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs1036606940; called by muse, mutect2, varscan2
- RAD54L | c.924T>A p.T308= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- SCUBE3 | c.2121G>A p.Q707= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV99235385; called by muse, mutect2, varscan2
- SLC25A42 | c.66G>A p.S22= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs758484747, COSV59380691; called by muse, mutect2, varscan2
- SLC47A1 | c.1269C>T p.I423= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs774900748, COSV99565586; called by muse, mutect2, varscan2
- STEAP2 | c.1134T>C p.S378= | Silent (SNP) | VAF 42/76 reads (55%) | called by muse, mutect2, varscan2
- TSSK1B | c.12T>C p.A4= | Silent (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2, varscan2
- TTI1 | c.1368G>C p.L456= | Silent (SNP) | VAF 8/69 reads (12%) | called by muse, mutect2, varscan2
- VPS45 | c.306C>T p.I102= | Silent (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- YEATS2 | c.2712A>G p.G904= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- ZMYM1 | c.699G>A p.E233= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100721145, COSV63252416; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504717 del TA | 5'Flank (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel, varscan2
- MIR519D | n.35C>T | RNA (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- S100A7A | c.-1G>C | 5'UTR (SNP) | VAF 17/81 reads (21%) | catalogued as rs750574641; called by muse, mutect2, varscan2
- SNORD116-13 | n.56G>A | RNA (SNP) | VAF 8/67 reads (12%) | catalogued as rs975998174; called by muse, mutect2, varscan2
